FM case AD6067 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS.
https://portal.gdc.cancer.gov/cases/7288b8be-52a5-4bb3-bcae-a307c7675bf2

Female, 53.6 years: Endometrioid adenocarcinoma, NOS (ICD-O-3 8380/3) of the uterus; metastasis biopsied or resected from the ovary. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
